Somatic mutation profile of tumor specimen TCGA-EI-6508-01A (aliquot TCGA-EI-6508-01A-11D-1733-10) from TCGA case TCGA-EI-6508, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 48.8 years (17,827 days).
Specimen TCGA-EI-6508-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fa2d1f7-91cf-4188-ba82-051d8d34339b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6508-10A (Blood Derived Normal), aliquot TCGA-EI-6508-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/192f0279-2485-44f3-9dc3-4d29c0dd0cbd

The open-access MAF lists 119 somatic variants for this specimen: 89 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 25, Nonsense Mutation 6, Intron 2, In Frame Del 2, RNA 2, 5'Flank 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASR | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as rs1085307984, CM107259, COSV56134117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 28/34 reads (82%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs369836113; called by muse, mutect2, varscan2
- ADARB2 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0.025); catalogued as rs150320038; called by muse, mutect2, varscan2
- ADGRG4 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775821351, COSV54959480; called by muse, mutect2, varscan2
- ALDH1A2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179237166, COSV51083375; called by muse, varscan2
- ALYREF | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.576); catalogued as rs1197791254, COSV58668289; called by muse, mutect2, varscan2
- ANKRD36B | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 210/380 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs369666439; called by muse, mutect2, varscan2
- AP3B2 | c.2788G>A p.E930K (on ENST00000261722; = p.E924K on NM_004644.5) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.53); catalogued as rs750043916, COSV55605956, COSV55610557; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 48/135 reads (36%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- ASB16 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs1210036452, COSV53235244; called by muse, mutect2, varscan2
- AZGP1 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV52798123; called by muse, mutect2, varscan2
- B4GALNT4 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV57323121, COSV57323977; called by mutect2, varscan2
- C12orf4 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54206006, COSV99712518; called by muse, mutect2, varscan2
- C3orf38 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1192759590, COSV59628366; called by muse, mutect2, varscan2
- CCDC3 | c.790C>A p.R264S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV66559153, COSV66560289; called by muse, mutect2, varscan2
- CDC14A | c.1714C>A p.L572I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as COSV60559583; called by muse, mutect2, varscan2
- CEP152 | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57860720; called by muse, mutect2, varscan2
- CFAP47 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.049); catalogued as rs145395039, COSV52886807; called by muse, mutect2, varscan2
- COG5 | c.2333T>G p.V778G (on ENST00000347053 / NM_001379512.1; = p.V799G on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV51754809; called by muse, mutect2, varscan2
- COL3A1 | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV58590672, COSV58590878; called by muse, mutect2, varscan2
- CPXM2 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53864042, COSV99580821; called by muse, mutect2, varscan2
- CSDC2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV53447926; called by muse, mutect2, varscan2
- DMBT1 | c.7400G>A p.R2467H (on ENST00000338354 / NM_001377530.1; = p.R1710H on NM_004406.3) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs373485754; called by muse, mutect2, varscan2
- DNAH5 | c.12649T>A p.F4217I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV99444159; called by muse, mutect2, varscan2
- DTD1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs777964321, COSV66280096; called by muse, mutect2, varscan2
- EHMT2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1405497274, COSV64996117; called by muse, mutect2, varscan2
- EMD | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782768362, COSV63962163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVA1C | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146340457; called by muse, mutect2, varscan2
- FAM120A | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1366960810, COSV52906742; called by muse, mutect2, varscan2
- FAM135B | c.1425A>C p.E475D | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99417889, COSV99427864; called by muse, mutect2, varscan2
- FKBP14 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.104); catalogued as COSV56107556; called by muse, mutect2, varscan2
- FNDC8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.214); catalogued as rs1433675700, COSV50101905; called by muse, mutect2, varscan2
- GALNT7 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV53931456; called by muse, mutect2, varscan2
- GPAT2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1373385929; called by mutect2, varscan2
- HIP1R | c.2585A>T p.Y862F | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99458112; called by muse, varscan2
- HIP1R | c.2586C>G p.Y862* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as COSV99458113; called by muse, varscan2
- HIP1R | c.2587G>T p.A863S | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53442467; called by muse, varscan2
- INTU | c.1648T>G p.L550V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV58872613; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs569293395, COSV59825406; called by muse, mutect2, varscan2
- KCNH1 | c.1976C>A p.A659D (on ENST00000271751 / NM_172362.3; = p.A632D on NM_002238.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336751620, COSV55087506; called by muse, mutect2, varscan2
- LRP8 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364401690, COSV60099383; called by muse, mutect2, varscan2
- MAGEC2 | c.918T>A p.H306Q | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55999947; called by muse, mutect2, varscan2
- MAMDC2 | c.1832T>A p.L611H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65858735; called by muse, mutect2, varscan2
- MAN2C1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99145182; called by muse, mutect2, varscan2
- MAP3K21 | c.1561C>G p.H521D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64041993; called by muse, mutect2, varscan2
- MID1 | c.1946C>T p.T649M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.73); catalogued as COSV58192074; called by muse, mutect2, varscan2
- MKI67 | c.4868A>G p.D1623G | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs950589142, COSV64075113; called by muse, mutect2, varscan2
- MUC16 | c.11080A>C p.S3694R | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV67474994; called by muse, mutect2, varscan2
- MYLK3 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67364958; called by muse, mutect2, varscan2
- MYO5C | c.4560G>C p.E1520D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.488); catalogued as COSV55907968; called by muse, mutect2, varscan2
- OR4C12 | c.294A>T p.Q98H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100078593, COSV58860343; called by muse, mutect2, varscan2
- OR8K1 | c.636T>A p.N212K | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV54402856; called by muse, mutect2, varscan2
- PARPBP | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59674444; called by muse, mutect2, varscan2
- PCDHAC2 | c.2246G>T p.R749M | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV53855874; called by muse, mutect2, varscan2
- PCDHGA8 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.474); catalogued as rs1561651112, COSV53971050; called by muse, mutect2, varscan2
- PHIP | c.5113T>G p.L1705V | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as COSV51506242; called by muse, mutect2, varscan2
- PIGS | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as COSV52025092; called by muse, mutect2, varscan2
- PLXND1 | c.3080G>A p.R1027H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs754831143, COSV100139495, COSV60712258; called by muse, mutect2, varscan2
- POLR2A | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs1052109875, COSV59493280; called by muse, mutect2, varscan2
- RHOH | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV67805979; called by muse, mutect2, varscan2
- RNF24 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.068); catalogued as COSV100270599; called by muse, mutect2, varscan2
- RPAP1 | c.3278C>T p.T1093M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs748913456, COSV58538171; called by muse, mutect2, varscan2
- SAA2 | c.137A>C p.N46T | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV56777369; called by muse, mutect2, varscan2
- SACS | c.9433G>T p.E3145* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV66533910; called by muse, varscan2
- SACS | c.9409G>A p.D3137N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66537785; called by muse, varscan2
- SACS | c.9097G>T p.D3033Y | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV66542159; called by muse, varscan2
- SACS | c.9042G>A p.W3014* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as COSV66542171; called by muse, varscan2
- SDK1 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs371559284; called by muse, mutect2, varscan2
- SEMA3F | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV50030877; called by muse, mutect2, varscan2
- SLC25A2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1554296137, COSV53404197; called by muse, mutect2, varscan2
- SLC9A9 | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100339167; called by muse, mutect2, varscan2
- SMAD4 | c.1484T>G p.L495R | Missense Mutation (SNP) | VAF 68/106 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100747439, COSV61687895; called by muse, mutect2, varscan2
- SPIRE2 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65556356; called by muse, mutect2, varscan2
- STXBP2 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.102); catalogued as COSV99656930; called by muse, mutect2, varscan2
- TBXAS1 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs200831963, COSV54947615; called by muse, mutect2, varscan2
- TESK2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs374778347; called by muse, mutect2, varscan2
- TLN2 | c.272A>T p.K91I | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60891160; called by muse, mutect2, varscan2
- TNPO1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1278439280, COSV100472947, COSV61521087; called by muse, mutect2, varscan2
- TTN | c.45670G>T p.G15224W (on ENST00000591111; = p.G7800W on NM_003319.4) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | PolyPhen probably damaging (0.957); catalogued as COSV60145814; called by muse, mutect2, varscan2
- UBR7 | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50150048; called by muse, mutect2, varscan2
- VWA3A | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs564353975, COSV55391763; called by muse, mutect2, varscan2
- AGAP3 | c.58G>A p.G20R (on ENST00000622464; = p.G56R on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF3K | c.150_158del p.L51_L53del | In Frame Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- NGEF | c.527_550del p.G176_R183del | In Frame Del (DEL) | VAF 49/165 reads (30%) | called by mutect2, pindel, varscan2
- RNF213 | c.14799del p.L4934Sfs*38 | Frame Shift Del (DEL) | VAF 27/42 reads (64%) | called by mutect2, pindel, varscan2
- SOX9 | c.1180dup p.R394Pfs*184 | Frame Shift Ins (INS) | VAF 16/32 reads (50%) | called by mutect2, pindel, varscan2
- ZNF385B | c.1093T>A p.C365S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABO | c.777G>A p.E259= | Silent (SNP) | VAF 70/88 reads (80%) | catalogued as COSV101505923; called by muse, mutect2, varscan2
- ANK3 | c.7986C>T p.A2662= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as rs147625375; ClinVar: likely benign; called by muse, mutect2, varscan2
- CC2D2A | c.921G>A p.R307= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV67504157; called by muse, mutect2, varscan2
- CECR2 | c.3363G>A p.P1121= (on ENST00000342247 / NM_001290047.2; = p.P937= on NM_001290046.1) | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as rs960677521, COSV52843611; called by muse, varscan2
- CHSY3 | c.2188C>A p.R730= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV59279786; called by muse, mutect2, varscan2
- DLC1 | c.459C>A p.I153= | Silent (SNP) | VAF 50/174 reads (29%) | catalogued as COSV99360573; called by muse, mutect2, varscan2
- DLGAP1 | c.171C>T p.C57= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs758188816, COSV59807209; called by muse, mutect2, varscan2
- EGR2 | c.501G>A p.P167= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs756375039, COSV54347542; called by muse, mutect2, varscan2
- EIF5 | c.1236G>A p.P412= | Silent (SNP) | VAF 48/62 reads (77%) | catalogued as rs140137312; called by muse, mutect2, varscan2
- HAPLN4 | c.363C>T p.D121= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs747149819, COSV52270068; called by muse, mutect2, varscan2
- HPS5 | c.2988G>A p.L996= (on ENST00000349215 / NM_181507.2; = p.L882= on NM_007216.4) | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV61687632; called by muse, mutect2, varscan2
- KPNA2 | c.1341C>T p.I447= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1308451187, COSV100388798, COSV57857215; called by muse, mutect2, varscan2
- MAGEE1 | c.822C>T p.P274= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV63910674; called by muse, mutect2, varscan2
- MXRA5 | c.8418C>A p.G2806= | Silent (SNP) | VAF 137/405 reads (34%) | catalogued as COSV54239355; called by muse, mutect2, varscan2
- NOX4 | c.723G>A p.E241= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- PARM1 | c.225T>G p.S75= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV56653782, COSV56655210; called by muse, mutect2, varscan2
- PLIN5 | c.102C>T p.A34= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV60547719; called by muse, mutect2, varscan2
- PRR16 | c.825C>T p.F275= (on ENST00000407149 / NM_001300783.2; = p.F252= on NM_016644.2) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV65401020; called by muse, mutect2, varscan2
- PSKH2 | c.630C>T p.S210= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as rs376242267; called by muse, mutect2, varscan2
- SPATA31E1 | c.1411C>T p.L471= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57792860; called by muse, mutect2, varscan2
- TNS1 | c.1176C>T p.T392= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs1041583492, COSV50714496; called by muse, mutect2, varscan2
- TTLL3 | c.1917C>T p.R639= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs759555843, COSV59614302; called by muse, mutect2, varscan2
- UGT2A1 | c.1497G>T p.V499= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV54142976; called by muse, mutect2, varscan2
- XIRP1 | c.3741G>A p.P1247= | Silent (SNP) | VAF 71/164 reads (43%) | catalogued as rs770016283, COSV61139200; called by muse, mutect2, varscan2
- ZFHX4 | c.8769T>C p.S2923= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51447364; called by muse, mutect2, varscan2
- ATP6AP1L | n.1748C>T | RNA (SNP) | VAF 21/46 reads (46%) | catalogued as rs371506768; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457881 C>T | 5'Flank (SNP) | VAF 19/91 reads (21%) | catalogued as rs778717171; called by muse, mutect2, varscan2
- HNMT | c.190+11034C>T | Intron (SNP) | VAF 38/101 reads (38%) | catalogued as rs138107961; called by muse, mutect2, varscan2
- KIF16B | c.3498+3118G>A | Intron (SNP) | VAF 34/124 reads (27%) | catalogued as rs776754950, COSV61701626; called by muse, mutect2, varscan2
- TUBB7P | n.136C>T | RNA (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
